Gene-level copy-number profile of tumor specimen TCGA-FD-A5BY-01A from TCGA case TCGA-FD-A5BY, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 63.2 years (23,080 days).
Specimen TCGA-FD-A5BY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.3ab080a6-8737-4b36-b845-5d15f59ddba1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A5BY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e4e65cb-092f-4654-a392-ec1588b505a4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,176; copy number 2: 39,060; copy number 3: 4,689; copy number 4: 892.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A5BY-01A-31D-A288-01): tumor purity 0.58, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 15,176. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
